Gene-level copy-number profile of tumor specimen TCGA-A2-A25B-01A from TCGA case TCGA-A2-A25B, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 39.6 years (14,454 days).
Specimen TCGA-A2-A25B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.716578b3-e202-483b-b15c-784f5a0c60f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A25B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/667fdeec-a337-485f-a39c-b76930e43013

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 179; copy number 1: 9,341; copy number 2: 20,016; copy number 3: 13,308; copy number 4: 8,276; copy number 5: 4,230; copy number 6: 844; copy number 7: 1,686; copy number 8: 394; copy number 9: 468; copy number 10: 46; copy number 11: 60; copy number 13: 348; copy number 14: 90; copy number 15: 100; copy number 16: 31; copy number 17: 82; copy number 18: 9; copy number 19: 172; copy number 22: 8; copy number 23: 2; copy number 27: 21; copy number 28: 3; copy number 33: 43; copy number 35: 6; copy number 42: 3; copy number 50: 37.

Homozygous deletions (total copy number 0; autosomes only): 179 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:23,403,848–23,856,375, 10 genes (within-gene range 0–3): AC100756.3, HERC2P6, GOLGA6L2, MIR4508, MKRN3, AC126407.1, MAGEL2, NDN, AC087490.1, RNU6-741P.
- chr15:24,101,827–24,823,365, 1 gene (within-gene range 0–3): PWRN1.
- chr15:24,558,060–25,581,122, 105 genes (broad region; genes not listed).
- chr15:29,664,477–31,042,302, 63 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,683 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,017,468–164,980,137, 800 genes, copy number 5 (broad region; genes not listed).
- chr1:166,975,582–173,207,331, 143 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:174,892,417–229,689,904, 1,051 genes, copy number 6–8 (broad region; genes not listed).
- chr1:241,413,716–248,919,946, 216 genes, copy number 9 (broad region; genes not listed).
- chr2:165,747,588–169,115,680, 35 genes, copy number 5 (within-gene range 3–5): GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6.
- chr2:169,767,185–173,298,512, 59 genes, copy number 6: PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18.
- chr3:11,745–5,180,911, 52 genes, copy number 5–6 (within-gene range 2–6): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4, CNTN4-AS1, IL5RA, AC024060.1, TRNT1, CRBN, AC024060.2, AC034195.1, SUMF1, LRRN1, AC023480.1, PNPT1P1, AC023483.1, SETMAR, MRPS10P2, ITPR1-DT, ITPR1, EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B.
- chr3:165,772,904–198,222,513, 629 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–43,280,850, 677 genes, copy number 7–9 (broad region; genes not listed).
- chr6:6,794,915–8,102,559, 31 genes, copy number 10: BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1.
- chr7:103,030,104–106,838,480, 61 genes, copy number 5 (broad region; genes not listed).
- chr7:139,561,570–159,233,377, 501 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (broad region; genes not listed).
- chr12:48,935,723–95,003,748, 1,029 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:18,333,726–20,060,983, 89 genes, copy number 14 (broad region; genes not listed).
- chr14:32,934,396–40,390,547, 125 genes, copy number 5–15 (within-gene range 4–15) (broad region; genes not listed).
- chr15:39,167,676–39,310,782, 3 genes, copy number 28: AC113146.1, C15orf54, AC013652.2.
- chr15:49,326,962–50,418,692, 21 genes, copy number 27 (within-gene range 3–27): FAM227B, AC022306.2, AC022306.3, AC022306.1, FGF7, DTWD1, AC025040.2, ATP8B4, AC025040.1, RNA5SP394, SLC27A2, Y_RNA, HDC, RN7SL494P, GABPB1, RNU6-94P, GABPB1-IT1, GABPB1-AS1, AC022087.1, MIR4712, AHCYP7.
- chr15:86,932,880–101,933,350, 353 genes, copy number 5–50 (broad region; genes not listed).
- chr17:28,546,708–30,959,322, 142 genes, copy number 7 (broad region; genes not listed).
- chr17:34,837,871–35,726,413, 53 genes, copy number 6: AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL, AC004223.3, AC004223.4, AC004223.2, AC004223.1, RAD51D, RNU6-840P, Vault, FNDC8, NLE1, UNC45B, AC022916.4, AC022916.2, AC022916.3, SLC35G3, AC022916.1, SLFN5, AC022706.1, AC060766.2, SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1.
- chr17:35,731,639–35,753,239, 2 genes, copy number 6: RASL10B, GAS2L2.
- chr17:48,026,167–78,225,636, 876 genes, copy number 5–19 (broad region; genes not listed).
- chr17:78,787,381–83,095,122, 201 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,861. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
